Somatic mutation profile of tumor specimen TARGET-30-PASLXS-01A (aliquot TARGET-30-PASLXS-01A-01D) from TARGET case TARGET-30-PASLXS, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.4 years (859 days).
Specimen TARGET-30-PASLXS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 025e05b6-019e-4e69-b571-1aaf930c680f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASLXS-10A (Blood Derived Normal), aliquot TARGET-30-PASLXS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6095aef-3ee5-4b22-b61f-c603ad4e3f25

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV52771366, COSV52826932, COSV52883452; called by muse, mutect2, varscan2
- TP53 | c.165T>C p.T55= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV53293945; called by muse, mutect2, varscan2
- ATP1A2 | c.*394C>A | 3'UTR (SNP) | VAF 40/137 reads (29%) | catalogued as COSV63404769; called by muse, mutect2, varscan2
